Somatic mutation profile of tumor specimen MMRF_2839_1_BM_CD138pos (aliquot MMRF_2839_1_BM_CD138pos_T1_KHS5U_L16573) from MMRF case MMRF_2839, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.2 years (21,979 days).
Specimen MMRF_2839_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdcf9207-69a3-40af-b78f-11f224708e14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2839_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2839_1_PB_WBC_C2_KHS5U_L16671; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa43938f-4760-48b2-b246-2c82c5b8e9aa

The open-access MAF lists 77 somatic variants for this specimen: 25 protein-altering or splice-affecting, 3 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 30, Missense Mutation 17, Intron 11, Nonsense Mutation 4, Silent 3, 5'UTR 3, 3'Flank 2, Frame Shift Del 2, RNA 2, Splice Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAHCC1 | c.5447G>A p.G1816E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1162151848; called by mutect2, varscan2
- MEGF6 | c.3014G>A p.C1005Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs764683291; called by muse, mutect2, varscan2
- PDE6C | c.2426G>A p.R809K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1039997248; called by muse, mutect2, varscan2
- PRDM13 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 128/349 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100980536; called by muse, varscan2
- RAPH1 | c.2294del p.P765Hfs*19 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | catalogued as rs760908242; called by mutect2, varscan2
- TMC3 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs201198651; called by muse, mutect2, varscan2
- UGT2B11 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.424); catalogued as rs1221679606; called by muse, mutect2
- ZNF471 | c.33G>A p.Q11= | Splice Region (SNP) | VAF 220/249 reads (88%) | catalogued as rs766883710; called by muse, mutect2, varscan2
- ANKRD13A | c.687C>A p.S229R | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- APC2 | c.4927C>T p.P1643S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- C2orf78 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 86/179 reads (48%) | called by muse, mutect2, varscan2
- DGKB | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- FCRL6 | c.817A>G p.N273D | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- HELB | c.916A>G p.R306G | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- HSD11B1L | c.823C>G p.Q275E | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.539); called by muse, mutect2
- MSX1 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- NKD1 | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 124/338 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PMS1 | c.1364A>G p.K455R | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PTPN14 | c.364G>T p.V122F | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- RMC1 | c.923C>G p.P308R | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, varscan2
- TASOR2 | c.75_78del p.I26Ffs*9 | Frame Shift Del (DEL) | VAF 44/100 reads (44%) | called by pindel, varscan2
- TEX101 | c.686T>G p.I229S (on ENST00000598265 / NM_001130011.3; = p.I247S on NM_031451.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TLE1 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- TPR | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 34/172 reads (20%) | called by muse, mutect2, varscan2
- WDFY4 | c.4066+1G>T p.X1356_splice | Splice Site (SNP) | VAF 60/100 reads (60%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.3627G>A p.R1209= | Silent (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2, varscan2
- SPRR1A | c.207G>T p.V69= | Silent (SNP) | VAF 93/484 reads (19%) | called by muse, mutect2, varscan2
- TEX13A | c.657C>T p.A219= | Silent (SNP) | VAF 40/46 reads (87%) | called by muse, varscan2
- AC020688.1 | n.475C>T | RNA (SNP) | VAF 44/141 reads (31%) | catalogued as rs1383552958; called by muse, mutect2, varscan2
- ACER2 | c.*532C>A | 3'UTR (SNP) | VAF 100/186 reads (54%) | called by muse, mutect2, varscan2
- AK5 | c.248-22_248-21del | Intron (DEL) | VAF 24/52 reads (46%) | called by mutect2, pindel, varscan2
- AL391650.1 | c.*791C>A | 3'UTR (SNP) | VAF 6/12 reads (50%) | catalogued as rs1194267093; called by muse, mutect2
- ALS2 | c.1113+1168T>A | Intron (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- ANK1 | c.126+68084G>C | Intron (SNP) | VAF 12/18 reads (67%) | catalogued as rs1018554944; called by muse, mutect2, varscan2
- CEBPA | c.*966C>T | 3'UTR (SNP) | VAF 38/78 reads (49%) | catalogued as rs1001741074; called by muse, varscan2
- CNTNAP2 | c.*3595C>A | 3'UTR (SNP) | VAF 108/244 reads (44%) | called by muse, mutect2, varscan2
- CTSC | c.318+6955T>G | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- DOCK8 | c.53+126C>T | Intron (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- FADD | c.*36C>A | 3'UTR (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- FBP2 | c.*182A>C | 3'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- FBP2 | c.*181A>G | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- GBGT1 | c.359+27G>T | Intron (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- GIMAP1 | c.*2226_*2227del | 3'UTR (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- GNL1 | c.-138G>A | 5'UTR (SNP) | VAF 48/82 reads (59%) | called by muse, mutect2, varscan2
- GRIK5 | chr19:42065806 G>A | 5'Flank (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- GTF2H3 | c.*1563G>T | 3'UTR (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- HAUS6P3 | n.859C>A | RNA (SNP) | VAF 60/158 reads (38%) | called by muse, mutect2, varscan2
- HEATR5B | c.*317T>C | 3'UTR (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- IFITM10 | c.*2558C>A | 3'UTR (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- KIAA0895 | c.179-9387G>C | Intron (SNP) | VAF 34/58 reads (59%) | called by mutect2, varscan2
- LASP1 | c.612+56C>G | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- LMAN1 | c.*1337del | 3'UTR (DEL) | VAF 37/99 reads (37%) | called by mutect2, pindel, varscan2
- LRRN1 | c.*391T>A | 3'UTR (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- LSM8 | c.*336A>C | 3'UTR (SNP) | VAF 51/104 reads (49%) | called by muse, mutect2, varscan2
- NKX3-1 | c.*1075T>G | 3'UTR (SNP) | VAF 8/14 reads (57%) | catalogued as rs1323121304; called by muse, varscan2
- NOG | c.*96G>T | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- NR2F2 | c.*272G>C | 3'UTR (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- PAX5 | c.-19C>G | 5'UTR (SNP) | VAF 40/74 reads (54%) | called by muse, varscan2
- POLR3B | c.*281A>T | 3'UTR (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- RAB1B | c.*186T>A | 3'UTR (SNP) | VAF 47/89 reads (53%) | called by muse, varscan2
- RECQL5 | c.1229+386C>G | Intron (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2
- RNF152 | c.*4417C>A | 3'UTR (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- ROBO1 | c.*829C>G | 3'UTR (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- SAMD13 | chr1:84350176 G>A | 3'Flank (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- SLC17A4 | c.-32T>C | 5'UTR (SNP) | VAF 186/427 reads (44%) | called by muse, mutect2, varscan2
- SLC1A1 | c.*442T>C | 3'UTR (SNP) | VAF 60/133 reads (45%) | called by muse, mutect2, varscan2
- SLC4A8 | c.1102-475T>A | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2
- SLC4A8 | c.1102-473T>A | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2
- SNX20 | c.*1409A>T | 3'UTR (SNP) | VAF 87/226 reads (38%) | called by muse, mutect2, varscan2
- SOGA1 | c.*676G>A | 3'UTR (SNP) | VAF 26/276 reads (9%) | catalogued as rs1362611530; called by muse, mutect2, varscan2
- SSR1 | c.*4063C>T | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2
- TGFBR3 | c.*64C>A | 3'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- TLCD4-RWDD3 | c.*613_*616del | 3'UTR (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- TNFRSF10B | c.*591C>G | 3'UTR (SNP) | VAF 12/19 reads (63%) | catalogued as rs563918905; called by muse, varscan2
- TSPAN5 | c.*794C>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- VANGL1 | c.*303del | 3'UTR (DEL) | VAF 8/114 reads (7%) | called by mutect2, pindel*
- WTAP | chr6:159761300 A>G | 3'Flank (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
